Gene-level copy-number profile of tumor specimen TCGA-94-7557-01A from TCGA case TCGA-94-7557, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.4 years (26,802 days).
Specimen TCGA-94-7557-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.84f04067-6d84-4aa1-81ff-6b74f8911fb4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-94-7557-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5d5790c-b7f0-4d57-8178-c162bb06517f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 793; copy number 2: 17,058; copy number 3: 15,805; copy number 4: 20,150; copy number 5: 1,011; copy number 6: 4,334; copy number 7: 393; copy number 8: 154; copy number 9: 17; copy number 10: 31; copy number 13: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-94-7557-01A-11D-2121-01): tumor purity 0.46, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,278,050–25,089,151, 57 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 62 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,267,798–210,304,540, 24 genes, copy number 10: ATP5MC2P1, LINC01696, LINC01698, MIR205HG, MIR205, AL023754.1, AL023754.2, CAMK1G, LAMB3, MIR4260, HSD11B1-AS1, G0S2, HSD11B1, ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25, SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1.
- chr1:240,489,573–240,776,824, 11 genes, copy number 13 (within-gene range 8–13): GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,998,794, 3 genes, copy number 13: RFKP1, HNRNPA1P42, AL590682.1.
- chr5:26,669,346–27,121,150, 7 genes, copy number 10: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P.
- chr7:17,299,295–17,558,909, 4 genes, copy number 9 (within-gene range 6–9): AC019117.3, SNORA63, AC019117.2, AC019117.1.
- chr15:25,333,728–25,439,051, 1 gene, copy number 9 (within-gene range 6–9): UBE3A.
- chr15:25,456,271–26,265,918, 12 genes, copy number 9: LINC02250, AC023449.1, ATP10A, RNA5SP390, MIR4715, AC016266.1, LINC02346, AC044913.2, AC044913.1, AC100836.1, LINC00929, AC012060.1.

Autosomal genes at a single copy (total copy number 1): 766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
